Somatic mutation profile of tumor specimen TARGET-10-PAPIIB-09A (aliquot TARGET-10-PAPIIB-09A-01D) from TARGET case TARGET-10-PAPIIB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,538 days).
Specimen TARGET-10-PAPIIB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a155af9-b20b-401b-87c3-d6de337017e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPIIB-10A (Blood Derived Normal), aliquot TARGET-10-PAPIIB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66d9cd64-b15b-407b-904c-c2e1a1454d86

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 5, Nonsense Mutation 3, 5'UTR 2, Splice Site 1, 3'UTR 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO6 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs727504567; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANGPT1 | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV52449117; called by muse, mutect2, varscan2
- GRM6 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99179406; called by muse, mutect2, varscan2
- TMEM231 | c.619G>C p.D207H (on ENST00000258173 / NM_001077418.3; = p.D236H on NM_001077416.2) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs192462687; called by muse, mutect2, varscan2
- TMEM33 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52562002; called by muse, mutect2, varscan2
- BID | c.49dup p.R17Pfs*18 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- CEP70 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CES2 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CTAGE1 | c.1739G>C p.G580A | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); called by muse, mutect2
- DHX34 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ELOA2 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.626); called by muse, mutect2
- FBXL13 | c.1745T>C p.L582S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF14 | c.3336-1G>C p.X1112_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- KIF1A | c.3128G>C p.R1043T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MCM5 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PRKCG | c.2031C>G p.N677K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- RNF40 | c.1891C>T p.L631F | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SLC4A5 | c.2628G>A p.W876* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- STAT5B | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.104); called by muse, mutect2
- SYNM | c.2251G>C p.E751Q | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TARS3 | c.1159A>G p.M387V | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- UNC5D | c.1601C>A p.S534* | Nonsense Mutation (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- C2orf16 | c.321C>G p.L107= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1287213504; called by muse, mutect2, varscan2
- MEGF8 | c.4422C>A p.G1474= (on ENST00000251268 / NM_001271938.2; = p.G1407= on NM_001410.3) | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1244636363; called by muse, mutect2
- MYO15B | c.4251G>A p.Q1417= | Silent (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- PDGFRA | c.2760C>T p.H920= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs368291181; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC19A2 | c.753G>A p.E251= | Silent (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 6/43 reads (14%) | catalogued as rs201441562; called by pindel, varscan2
- CCDC39 | c.-38G>A | 5'UTR (SNP) | VAF 4/12 reads (33%) | catalogued as rs1357214788; called by muse, mutect2, varscan2
- DEFB133 | c.60+85G>A | Intron (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- LAIR1 | c.-88C>T | 5'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- MED11 | c.217-76G>C | Intron (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- MID1 | c.660+1796G>C | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- SLC2A11 | c.21+63G>A | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs940623450; called by muse, mutect2
- UBBP4 | n.577C>A | RNA (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- VSTM2A | c.*2C>T | 3'UTR (SNP) | VAF 11/70 reads (16%) | catalogued as rs376012464; called by muse, mutect2, varscan2
